Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A77O, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A77O-01A (Primary Tumor).

[page 1 of 5]
Patient: [Redacted]

Referring Physician:

DOB: Age: Gender: F

Ref#: Hosn# Provider Group :

Date of Service: Date Received:

Case #:

Date Reported:

A copy of this report will be printed for: [Redacted]

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. - F.) HEAD OF PANCREAS, DISTAL STOMACH, DUODENUM, GALLBLADDER, APPENDIX, PANCREATODUODENECTOMY (WHIPPLE PROCEDURE, PARTIAL PANCREATECTOMY), CHOLECYSTECTOMY, APPENDECTOMY:
- INVASIVE MODERATELY DIFFERENTIATED DUCTAL ADENOCARCINOMA.
- 2.8 cm in maximum dimension.
- Confined to the pancreas.
- MARGINS: NEGATIVE FOR INVASIVE CARCINOMA.
- Mild dysplasia is present at the common bile duct margin.
- PERINEURAL INVASION: PRESENT.
- LYMPH-VASCULAR INVASION: PRESENT.
- FOUR OF TWENTY-SIX LYMPH NODES, POSITIVE FOR METASTASIS (4/26).
- PANCREATIC INTRAEPITHELIAL NEOPLASIA, GRADE 3 (PanIN-3).
- ACUTE AND CHRONIC PANCREATITIS.
- CHRONIC CHOLECYSTITIS.
- UNREMARKABLE VERMIFORM APPENDIX.
- SEE TUMOR STAGING SUMMARY BELOW.

PATHOLOGIC TUMOR STAGING SUMMARY:

Type and grade: Ductal adenocarcinoma, moderately differentiated.
Primary tumor: pT2 (2.8 cm in greatest dimension, limited to the pancreas).
Regional lymph nodes: pN1 (four of twenty-six lymph nodes, positive for metastasis).
Distant metastasis: Not applicable.
Lymphovascular invasion: Present.
Pathologic stage: IIB.
Margins: R0.

ICD-O.3

Adenocarcinoma, duct 850013

Site: Pancreas, head C250

9/19/13

Exocrine Pancreas Tumor Staging Information

(AJCC Cancer Staging Handbook, 7th Ed, and CAP protocol, June 2012)

Case #:

Printed:

Page 1

This report continues... (FINAL)

[page 2 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

Specimen:

Head of pancreas, distal stomach,
duodenum, common bile duct,
gallbladder, appendix.

Procedure:

Whipple procedure (partial
pancreatectomy), cholecystectomy,
appendectomy.

Tumor site:

Head of pancreas.

Tumor size:

2.8 cm in greatest dimension.

Histologic type:

Ductal adenocarcinoma.

Histologic grade:

Moderately differentiated, (G2).

Microscopic tumor extension:

Limited to the pancreas.

Margins:

Negative for invasive carcinoma.

Treatment effect:

Not applicable.

Lymph-vascular invasion:

Present.

Perineural invasion:

Present.

Lymph nodes:

Four of twenty-six lymph nodes,
positive for metastasis (4/26).

Pathologic Staging:

Primary tumor

pT2 (2.8 cm in greatest dimension,
limited to the pancreas).

Regional lymph nodes

pN1 (4/26 positive for metastasis).

Distant metastasis

Not applicable.

Pathologic stage

IIB.

Additional pathologic findings:

PanIN-3.

Acute and chronic pancreatitis.

Islet cell hyperplasia.

Signed

Source of Specimen:

A. Appendix

B. Gallbladder

Case #

Page 2

Printed:

This report continues... (FINAL)

Patient Name -

[page 3 of 5]
Patient:

Case #

FINAL SURGICAL PATHOLOGY REPORT

- C. Lymph node; Portal
- D. Whipple
- E. Final bile duct margin
- F. Bile duct new margin

Clinical History/Operative Dx:

Pancreatic cancer.

Intraoperative Diagnosis:

- C. Portal lymph node: Negative for metastasis.
- D. Whipple procedure: Pancreatic margin negative.
- E. (FSE) Final bile duct margin: Atypia suspicious for dysplasia.
- F. (FSF) New bile duct margin: Low grade dysplasia.

The intraoperative interpretation(s) was/were performed and rendered at

Gross Description:

A. The specimen is labeled appendix and is received in formalin. It consists of a very slightly curved vermiform appendix which is 4.8 cm in length and has a maximum diameter of 0.6 cm. The serosal surface is tan smooth and shiny. The appendiceal wall is intact. The mesoappendix is unremarkable. Representative sections are submitted in cassette A1 (proximal margin inked).

B. The specimen is labeled gallbladder and is received in formalin. It consists of a deflated but intact gallbladder which is 11 cm in length and up to 3.8 cm in diameter. The free serosal surface is red-violet and smooth. The cystic duct is patent and there are two firm pale tan cystic duct nodes which are up to 0.6 cm in maximum dimension. The gallbladder wall is generally 0.5 cm in thickness. The mucosa varies from yellow-tan to pale red and is finally granular throughout. There is partial septation of the gallbladder neck as well as an area of septation at the fundus. No calculi are present. There are no palpable nodules within the gastric wall. Representative sections re submitted. Section summary: B1) cystic duct margin, cystic duct nodes, gallbladder neck, B2) gallbladder body and fundus.

C. The specimen is labeled portal lymph node and consists of a 2 x 1.9 x 0.8 cm fragment of yellow-tan to pale red tissue. On sectioning there is a single lymph node measuring approximately 1.3 cm in maximum dimension. The node is sectioned and touch imprints are obtained. The specimen is entirely submitted in cassette C1.

D. The specimen is labeled Whipple procedure and is received without fixative. It consists of a composite resection of tissue which includes a 5 x 3 x 1.8 cm wedge resection of distal gastric tissue including pylorus and a 27 cm segment of duodenum. There is a firm portion of pancreatic head which measures 6.3 x 4.7 x 5 cm. The anterior-superior surface of the pancreas is inked blue, the anterior-inferior surface is inked green, and the posterior surface is inked black.

The free serosal surface of the gastric resection is pale red and smooth. There is a moderate amount of

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

adherent perigastric adipose tissue along what appears to be the greater curvature. The free serosal surface of the distal duodenum is tan with some slight surgical disruption but there are no areas of perforation. The specimen is opened to reveal the gastric mucosa is flat, tan to pale red, slightly granular. There is some slight irregularity of the mucosa at the pylorus but no true ulceration. The circumference at the proximal duodenum is 6 cm. The ampulla is located 10 cm distal to the pylorus (11.5 cm from proximal margin and 17 cm from the distal margin). A wire stent protrudes from the ampulla. Sectioning of the pancreas along the common bile duct reveals gritty tan-white, firm, poorly delineated neoplastic tissue in the head of the pancreas measuring 2.8 cm in maximum dimension. This neoplastic process grossly appears to be 1.8 cm from the ampulla. The pancreatic resection margin and the bile duct are marked with sutures. Sectioning reveals that the neoplasm is grossly 1.3 cm from the pancreatic resection margin. The neoplasm is in close proximity to the anterior-superior surface as well as the anterior-inferior surface. It is grossly 0.3 cm from the closest posterior pancreatic surface. Further sectioning of the pancreas reveals a prominent diverticulum-like out-pouching of the duodenum 2 cm proximal to the ampulla. This diverticular out pouching grossly extends into the head of the pancreas but does not appear to have neoplastic involvement. The pancreas tissue away from the neoplasm is firm and yellowish. There are scattered peripancreatic nodes which are up to 2.5 cm. The peripancreatic tissue is dissected for further nodes.

Just distal to the ampulla, the circumference of the duodenum is 7 cm and at the distal duodenal margin circumference is 5.5 cm. The duodenal mucosa is yellow-tan with normal appearing mucosal folds and no palpable areas of nodularity are present within the duodenal wall. There is very little duodenal adipose tissue present. The pancreatic resection margin is removed as a thin shave and submitted for frozen section as FSD1.

Section summary:

- D1) pancreatic resection margin from frozen section,
- D2) proximal gastric resection margin,
- D3) representative distal gastric tissue,
- D4) sections of pylorus,
- D5-D6) sections of ampulla (stent dissected free),
- D7-D8) diverticulum-like structure of duodenum extending into head of pancreas,
- D9-D12) anterior superior pancreas in vicinity of tumor,
- D13-D15) anterior inferior pancreas in vicinity of neoplasm
- D16-D18) posterior pancreas with closest approach of neoplasm,
- D19-D20) additional sections of distal common bile duct and neoplasm,
- D21) additional sections of body of pancreas adjacent to pancreatic resection margin,
- D22) distal duodenal margin,
- D23) possible nodes from perigastric adipose tissue,
- D24) one larger peripancreatic node, bivalved, two smaller nodes intact,
- D25) one large peripancreatic node, bivalved,
- D26) single prominent peripancreatic node, serially sectioned,
- D27) larger peripancreatic node, bivalved,
- D28) large peripancreatic node, bivalved,
- D29) four possible peripancreatic nodes, intact,
- D30) single peripancreatic node, bivalved,

Case #:

Printed:

Page 4

This report continues... (FINAL)

[page 5 of 5]
Patient:

Case #:

FINAL SURGICAL PATHOLOGY REPORT

D31) four smaller possible peripancreatic nodes. [REDACTED]

E. The specimen is labeled final bile duct margin and is received without fixative. It consists of a roughly cylindrical portion of tan to yellow-green tissue measuring 2 x 1.5 x 1 cm. A suture marks the true margin. The margin is removed as a thin shave and submitted for frozen section as FSE1. The tissue remaining from frozen section is submitted for permanent section in cassette E1. [REDACTED]

F. The specimen is labeled new bile duct margin and is received without fixative. It consists of a cylindrical portion of pale green tissue measuring 3.5 x 1.5 x 1.2 cm. A suture marks the true margin. The true margin is removed as a thin shave and submitted for frozen section as FSF1. The tissue remaining from frozen section is submitted for permanent section in cassette F1. [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Two lymph nodes are present, and are negative for metastatic carcinoma.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Sections demonstrate a single lymph node, negative for metastasis.

D. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Venous invasion is present. A total of twenty-three lymph nodes are present, four of which are positive for metastatic carcinoma.

E. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Histologic sections demonstrate a segment of common bile duct, with mild to moderate dysplasia. Invasive carcinoma is not identified.

F. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered. Histologic sections demonstrate a segment of common bile duct, with mild dysplasia. Invasive carcinoma is not identified.

Case #

Printed:

Page 5

END OF REPORT (FINAL)

Source: NCI Genomic Data Commons file ea2d980a-6e04-4822-86c0-295d38447e22 (TCGA-HZ-A77O.426F2D0F-C2A1-40FC-A001-83B737C0511C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).